Gene-level copy-number profile of tumor specimen TCGA-78-7159-01A from TCGA case TCGA-78-7159, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.9 years (22,261 days).
Specimen TCGA-78-7159-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.c8aa6c5b-7f79-4921-a47c-37cdebe9dc25.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,495 have no estimate.
https://portal.gdc.cancer.gov/files/42fd2b20-fea4-48ef-9127-9901b93898a0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 335; copy number 1: 1,359; copy number 2: 4,296; copy number 3: 23,439; copy number 4: 14,296; copy number 5: 5,394; copy number 6: 3,872; copy number 7: 2,137.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7159-01A-11D-2035-01): tumor purity 0.29, ploidy 3.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 335 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:162,322,188–187,748,199, 335 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,137 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:111,611,639–112,622,167, 30 genes, copy number 7: ANAPC1, RPL34P8, AC093166.1, CENPNP2, MIR4771-2, AC093166.2, EEF1E1P1, MERTK, RN7SL297P, RTRAFP1, SLC30A6P1, AC093675.1, TMEM87B, AC093675.2, FBLN7, AC092645.1, ZC3H8, AC092645.2, ZC3H6, NDUFB4P6, AC115115.1, RGPD8, VINAC1P, TTL, POLR1B, Y_RNA, CHCHD5, AC012442.2, AC012442.1, AC079922.1.
- chr3:71,675,414–74,136,892, 46 genes, copy number 7 (within-gene range 2–7): EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1, AC134508.2, AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, AC097369.4, SHQ1, AC134050.1, PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2.
- chr4:24,517,441–26,490,484, 37 genes, copy number 7: DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473, AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2, SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4, AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357, AC097714.1, RBPJ, CCKAR.
- chr4:27,133,996–27,140,051, 1 gene, copy number 7 (within-gene range 6–7): AC024132.2.
- chr4:29,465,701–29,510,737, 2 genes, copy number 7: AC092593.1, U6.
- chr8:36,887,456–144,261,940, 1,648 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr14:67,727,374–67,816,590, 1 gene, copy number 7 (within-gene range 6–7): ZFYVE26.
- chr14:67,799,004–70,247,801, 51 genes, copy number 7: AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3, BANF1P1, ACTN1-AS1, RPS29P1, DCAF5, DDX18P1, Y_RNA, AL391262.1, AL359317.2, EXD2, AL359317.1, GALNT16, AL157996.1, ERH, SLC39A9, AL157996.2, PLEKHD1, AL133445.1, CCDC177, AL133445.3, SUSD6, AL133445.2, SRSF5, SLC10A1, AL157789.1, SMOC1, RPL7AP6, SLC8A3, AL160191.1, AL160191.3, AL160191.2, ADAM21P1.
- chr15:88,459,501–89,679,427, 41 genes, copy number 7: AC013489.1, MRPS11, DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20, AC103982.1, ACAN, HAPLN3, MFGE8, AC067805.1, KRT18P47, AC107954.1, AC013565.2, AC013565.1, AC013565.3, ABHD2, RNU7-195P, HMGB1P8, AC124068.1, RLBP1, FANCI, POLG, MIR6766, AC124068.2, AC133637.1, AC133637.2, MIR9-3HG, MIR9-3, RHCG, LINC00928, AC013391.3, AC013391.2, TICRR, AC013391.1, KIF7, PLIN1.
- chr16:18,983,934–26,607,396, 197 genes, copy number 7 (broad region; genes not listed).
- chr16:27,678,940–28,063,714, 6 genes, copy number 7: AC016597.1, AC016597.2, Y_RNA, GSG1L, RNU6-159P, RNU6-1241P.
- chr21:14,000,927–18,267,373, 74 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr21:20,597,953–20,828,622, 3 genes, copy number 7: AP001506.1, LINC00320, PPIAP1.

Autosomal genes at a single copy (total copy number 1): 1,359. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
